Surgical pathology report (de-identified scan), TCGA case TCGA-86-7701, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Asterand, specimen TCGA-86-7701-01A (Primary Tumor).

[page 1 of 2]
Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments	Formatted Path Report
					LUNG TISSUE CHECKLIST Specimen type: Excision of tumor Tumor site: Lung Tumor size: 2.5 x 2 x 0.5 cm Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Visceral pleura Other tumor nodules: Yes - Lymph nodes: Not specified Lymphatic invasion: Not specified Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: CD15+, CK7+, TTF1+, CK20-, CDX2-

[page 2 of 2]
ID	Laterality	Date of procurement
	Right-upper	

Source: NCI Genomic Data Commons file fe2ce2e7-aae1-42e1-93e4-7098d8eaae67 (TCGA-86-7701.711A97E9-AC1D-4F62-B488-A3EB8370841E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).